Somatic mutation profile of tumor specimen TCGA-C9-A480-01A (aliquot TCGA-C9-A480-01A-12D-A24D-08) from TCGA case TCGA-C9-A480, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 45.4 years (16,567 days).
Specimen TCGA-C9-A480-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eac0c5a0-8ccf-497b-a83f-6a32eca2f8fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C9-A480-10A (Blood Derived Normal), aliquot TCGA-C9-A480-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86ab0077-f0ce-4cd8-a2cd-6b9866bb8c34

The open-access MAF lists 53 somatic variants for this specimen: 35 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 17, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- FLI1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773148506, CM1511325, COSV55648982; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 61/107 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASB4 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.206); catalogued as COSV99987082; called by muse, mutect2, varscan2
- BCAN | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs748416928, COSV100227782; called by muse, mutect2, varscan2
- C3orf56 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101228913, COSV67756507; called by muse, mutect2, varscan2
- CRB1 | c.1899G>T p.M633I | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100957597, COSV100957610; called by muse, mutect2, varscan2
- CYP1B1 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV99307108; called by muse, mutect2, varscan2
- CYP2E1 | c.1426A>G p.I476V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1176734765, COSV99428741; called by muse, mutect2, varscan2
- DUSP1 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99495812; called by muse, mutect2, varscan2
- DYNC1H1 | c.12425G>T p.G4142V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV100794156; called by muse, mutect2, varscan2
- FAM219B | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1451827953, COSV100715162, COSV62947171; called by muse, mutect2, varscan2
- FAM47A | c.231A>C p.L77F | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.188); catalogued as COSV60497079; called by muse, mutect2, varscan2
- GABRG2 | c.1333G>A p.G445S (on ENST00000361925 / NM_001375343.1; = p.G405S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); catalogued as rs1229153846, COSV62716939; called by muse, mutect2, varscan2
- GCLC | c.379G>A p.A127T (on ENST00000643939; = p.A131T on NM_001498.4) | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV99988212; called by muse, mutect2, varscan2
- GCN1 | c.7286C>T p.S2429L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs898548949, COSV100324453, COSV100324981; called by muse, mutect2, varscan2
- IKZF1 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100497809; called by muse, mutect2, varscan2
- INPP4A | c.2311C>T p.R771W (on ENST00000074304 / NM_001134224.1; = p.R732W on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50801502; called by muse, mutect2
- MOS | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61336613; called by muse, mutect2, varscan2
- MPZL3 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1346332239, COSV99636068; called by muse, mutect2
- MUC16 | c.42307G>T p.E14103* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV101109401, COSV66694165; called by muse, mutect2, varscan2
- MYO1F | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1194330833, COSV57798124; called by muse, mutect2, varscan2
- OR4D11 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100506437, COSV100506649; called by muse, mutect2, varscan2
- OR5F1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV99558300; called by muse, mutect2, varscan2
- POSTN | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV101123191; called by muse, mutect2, varscan2
- RASSF2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as rs149919336; called by muse, mutect2, varscan2
- SDAD1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1268126629, COSV62402512; called by muse, mutect2, varscan2
- SIAH1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV99588680; called by muse, mutect2, varscan2
- SLC26A2 | c.1438A>C p.K480Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); catalogued as COSV99639917; called by muse, mutect2, varscan2
- SLC49A4 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs769669601, COSV53749501, COSV99658790; called by muse, mutect2, varscan2
- SPTLC1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99364406; called by muse, mutect2, varscan2
- TACC2 | c.5681C>T p.T1894M (on ENST00000334433; = p.T85M on NM_206861.3) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs141016456; called by muse, mutect2, varscan2
- NCMAP | c.105del p.V36Lfs*13 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- STX11 | c.601_602del p.R201Gfs*153 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by pindel, varscan2
- CLEC1B | c.414G>A p.L138= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV100045912, COSV53725732; called by muse, mutect2, varscan2
- DIDO1 | c.4689G>A p.A1563= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1042962941, COSV99824311; called by muse, mutect2, varscan2
- FOXL1 | c.165C>T p.I55= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100206050, COSV57213713; called by muse, mutect2, varscan2
- GLDC | c.348C>T p.I116= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs771610134, COSV58685728; called by muse, mutect2, varscan2
- HECW2 | c.1968G>A p.V656= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99645341; called by muse, mutect2, varscan2
- IMPG1 | c.183C>T p.F61= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs764226204, COSV64055878, COSV64057850; called by muse, mutect2, varscan2
- INTS10 | c.1020G>T p.P340= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV101208632; called by muse, mutect2, varscan2
- MED13L | c.5784C>T p.L1928= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV99927518; called by muse, mutect2, varscan2
- MEGF8 | c.771C>T p.L257= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs574819813, COSV99233926; called by muse, mutect2, varscan2
- NYAP2 | c.1371C>T p.Y457= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs750472721, COSV55998444; called by muse, mutect2, varscan2
- PCDHA11 | c.1617G>A p.A539= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as rs544150374, COSV100246845; called by muse, mutect2, varscan2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PNPT1 | c.807C>G p.T269= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99569470; called by muse, mutect2, varscan2
- RYR3 | c.2283C>T p.P761= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101211778; called by muse, mutect2, varscan2
- SCML4 | c.318G>A p.A106= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs371827897; called by muse, mutect2, varscan2
- STIM1 | c.189C>G p.L63= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV100330458; called by muse, mutect2, varscan2
- WNT9A | c.183G>A p.R61= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- GCSAML | c.-1G>T | 5'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100825844; called by muse, mutect2, varscan2
